Somatic mutation profile of tumor specimen TARGET-20-PARFAL-04A (aliquot TARGET-20-PARFAL-04A-01D) from TARGET case TARGET-20-PARFAL, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 19.0 years (6,922 days).
Specimen TARGET-20-PARFAL-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6f6db364-9d17-421d-8481-c9785e0691b9.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARFAL-14A (Bone Marrow Normal), aliquot TARGET-20-PARFAL-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f05a360f-0c1b-44e9-9373-183d659c2f05

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Nonsense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EZH2 | c.2054G>A p.R685H (on ENST00000460911 / NM_001203247.2; = p.R690H on NM_004456.5) | Missense Mutation (SNP) | VAF 11/155 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1554481435, COSV57446082; ClinVar: likely pathogenic; called by muse, mutect2
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 13/182 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 8/108 reads (7%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2
- EZH2 | c.100C>T p.R34* | Nonsense Mutation (SNP) | VAF 16/167 reads (10%) | catalogued as COSV57451724; called by muse, mutect2
- PIK3R5 | c.1168G>A p.G390S | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs750286052, COSV52657578; called by muse, mutect2, varscan2
- RUNX1T1 | c.*2556C>T | 3'UTR (SNP) | VAF 17/263 reads (6%) | catalogued as rs1052508056, COSV56139484; called by muse, mutect2
